Surgical pathology report (de-identified scan), TCGA case TCGA-G9-7522, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Roswell Park, specimen TCGA-G9-7522-01A (Primary Tumor).

[page 1 of 2]
SPECIMENS:

- A. PROSTATE
- B. LEFT PELVIC LYMPH NODES
- C. RIGHT PELVIC LYMPH NODES

SPECIMEN(S):

- A. PROSTATE
- B. LEFT PELVIC LYMPH NODES
- C. RIGHT PELVIC LYMPH NODES

DIAGNOSIS:

- A. PROSTATE, PROSTATECTOMY:
- ADENOCARCINOMA
- GLEASON'S GRADE 3+4 = 7/10
- COMPRISING <10% OF THE GLAND
- MULTIFOCAL, INVOLVING BOTH THE RIGHT AND LEFT LOBES
- NO EXTRAPROSTATIC EXTENSION IDENTIFIED
- NO SEMINAL VESICLE INVASION IDENTIFIED
- ALL MARGINS ARE NEGATIVE FOR MALIGNANCY
- NO ANGIOLYMPHATIC INVASION IDENTIFIED
- PERINEURAL INVASION IS PRESENT
- HIGH-GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA
- B. LYMPH NODES, LEFT PELVIC, BIOPSY:
- NO MALIGNANCY IDENTIFIED IN FIVE LYMPH NODES (0/5).
- C. LYMPH NODES, RIGHT PELVIC, BIOPSY:
- NO MALIGNANCY IDENTIFIED IN FOUR LYMPH NODES (0/4).

SYNOPTIC REPORT - PROSTATE GLAND

Specimens Involved

Specimens: A: PROSTATE

Location: Left

Right

Posterior lateral

Anterior

WHO CLASSIFICATION

Epithelial tumors

Adenocarcinoma 8140/3

Multicentricity: Yes

Gland Involvement: 10%

Gleason Grade/Sum:: Grade 3 + 4 , Sum 7

High Grade PIN Present: Yes

Perineural Invasion: Yes

Vascular/Lymphatic Invasion: No

Seminal Vesicle Invasion: No

Periprostatic Fat Involved: No

Bladder Neck Involved: No

Margins Involvement: No

Frozen Performed: No

Post Hormonal Therapy Change: No

Lymph Nodes: Negative Right 0 / 4 Left 0 / 5

Other Pathologic Findings: None identified

Pathological Staging (pTNM): T 2c N 0 M X

Pathological staging is based on the AJCC Cancer Staging Manual, 7th Edition

GROSS DESCRIPTION:

A. PROSTATE

Received fresh labeled with the patient's identification and "prostate" a 29 g resected prostate gland measuring 2.8 cm from right lateral to left lateral, 3.3 cm from anterior to posterior, and 2.1 cm from apex to base. The capsule is, smooth red, and intact. Ink code: Anterior-orange, posterior-black, right lateral-green, left lateral-yellow, base-blue, apex-red. After removal of apex to base, the prostate

[page 2 of 2]
weighs 17 g and has a nodular tan parenchyma. The right seminal vesicle is 4.6 x 2.3 x 0.5 cm and the left is 4.6 x 1.8 x 0.4 cm; they consist of cystic tan tissue. The right vas deferens is 3.5 x 0.8 cm and the left is 3.1 x 0.6 cm; they consist of tubular tan tissue. Tissue is procured (10 g); submitted entirely:

A1-A2: perpendicular section of apex

A3: level I, right side

A4: level I, left side

A5-A6: level II, right lateral and posterior capsule

A7: level II, left lateral and anterior capsule

A8: level III, right anterior

A9: level III, right posterior

A10: level III, left anterior

A11: level III, left posterior

A12: perpendicular section of right mid base

A13: perpendicular section of left mid base

A14-A15: perpendicular sections of right lateral base

A16-A17: perpendicular sections of left lateral base

A18: perpendicular section of right posterior base

A19: perpendicular section of left posterior base

A20: perpendicular section of right mid base urethral orifice margin

A21: perpendicular section of left mid base urethral orifice margin

A22: right seminal vesicle and vas deferens

A23: left seminal vesicle and vas deferens

B. LEFT PELVIC LYMPH NODES

Received in formalin labeled with the patient's identification and "left pelvic lymph nodes" are pieces of yellow-tan soft tissue, 4.7 x 3.5 x 1.1 cm containing 3 possible lymph nodes measuring 1.7 x 1 x 0.4 cm, 1.9 x 1.2 x 0.3 cm, and 3.2 x 1 x 0.5 cm. The largest lymph node is bisected and has a yellow-tan cut surface; submitted entirely:

B1: 1 bisected lymph node

B2: 2 lymph nodes

B3-B5: remainder of soft tissue

C. RIGHT PELVIC LYMPH NODES

Received in formalin labeled with the patient's identification and "right pelvic lymph node" are pieces of yellow-tan soft tissue in aggregate, 4.7 x 3.5 x 1 cm containing possible lymph nodes ranging from 0.3 x 0.2 x 0.2 cm to 2.1 x 1.5 x 0.4 cm. The largest lymph node is bisected and has a uniform yellow-tan cut surface; submitted entirely:

C1-C2: 2 possible lymph nodes in each cassette

C3: 1 bisected lymph node

C4-C5: remainder of soft tissue

CLINICAL HISTORY:

None given

PRE-OPERATIVE DIAGNOSIS:

Prostate cancer

Microscopic/Diagnostic Dictation: Pathologist, [REDACTED]

Final Review: Pathologist, [REDACTED]

Final: Pathologist, [REDACTED]

Source: NCI Genomic Data Commons file f7d49b23-d86f-4515-bfbc-2c38e2829a4d (TCGA-G9-7522.8D3C4720-F528-4A73-B2F0-95B2AAC093F2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).